Somatic mutation profile of tumor specimen MP2PRT-PARKBE-TMP1-A (aliquot MP2PRT-PARKBE-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARKBE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,813 days).
Specimen MP2PRT-PARKBE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48623d7c-7498-4233-abde-9418981d7e71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKBE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKBE-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebabd64f-f3c1-4944-8f78-c9701049359c

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH23 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 25/499 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs746487992, COSV99818581; called by muse, mutect2
- FAM47C | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 132/262 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs782690396, COSV63726245; called by muse, varscan2
- FCHSD2 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 113/366 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.968); catalogued as rs757495469, COSV100238386; called by muse, mutect2, varscan2
- GPR78 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 205/732 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs1308795803; called by muse, mutect2, varscan2
- KDR | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55772825, COSV55779397; called by muse, mutect2
- LLGL2 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 162/594 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373166096; called by muse, mutect2, varscan2
- ENG | c.690G>A p.G230= | Splice Region (SNP) | VAF 195/477 reads (41%) | called by muse, mutect2, varscan2
- EPHA3 | c.1684G>A p.V562I | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FHOD3 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- GRIK3 | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.356); called by muse, mutect2
- WDFY3 | c.5779G>A p.E1927K | Missense Mutation (SNP) | VAF 21/439 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2
- ALDH3A1 | c.570G>A p.T190= | Silent (SNP) | VAF 243/600 reads (41%) | catalogued as rs370424410, COSV99855852; called by muse, mutect2, varscan2
- BCL3 | c.189C>T p.G63= | Silent (SNP) | VAF 124/1376 reads (9%) | called by muse, mutect2
- FBXO2 | c.828C>T p.S276= | Silent (SNP) | VAF 224/944 reads (24%) | catalogued as rs562234561; called by muse, mutect2, varscan2
- FREM3 | c.2733C>T p.T911= | Silent (SNP) | VAF 26/443 reads (6%) | called by muse, mutect2
- IAPP | c.240G>A p.K80= | Silent (SNP) | VAF 20/247 reads (8%) | called by muse, mutect2
- MYH2 | c.3954T>C p.I1318= | Silent (SNP) | VAF 11/342 reads (3%) | called by muse, mutect2
- UNC79 | c.4938C>T p.D1646= (on ENST00000393151 / NM_001346218.2; = p.D1469= on NM_020818.5) | Silent (SNP) | VAF 44/584 reads (8%) | catalogued as rs1383745877, COSV99828394; called by muse, mutect2
